Gene-level copy-number profile of tumor specimen TCGA-CJ-5679-01A from TCGA case TCGA-CJ-5679, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 73.5 years (26,858 days).
Specimen TCGA-CJ-5679-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.f7272563-39ca-4a5d-bf68-a9d265470080.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CJ-5679-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/637820b5-6a1f-42b4-bc00-a0f7bb0a8f76

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 25; copy number 2: 21,310; copy number 3: 20,820; copy number 4: 11,653; copy number 5: 544; copy number 6: 2,871; copy number 7: 2,597.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CJ-5679-01A-11D-1530-01): tumor purity 0.74, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,597 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,952,625–148,420,998, 2,597 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
